Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65E, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65E-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODES, RIGHT PELVIC, SELECTIVE DISSECTION -
SIXTEEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/16).

PART 2: LYMPH NODES, LEFT PELVIC, SELECTIVE DISSECTION -
SEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, DUCTAL AND ACINAR TYPES, GLEASON SCORE $4 + 3 = 7$.
- B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 3.5 cm.
- C. CARCINOMA INVOLVES APPROXIMATELY 30% OF THE EXAMINED PROSTATE VOLUME.
- D. CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION OF THE RIGHT POSTERIOR APEX (slide 3W) AND RIGHT POSTERIOR BASE (slide 3Y).
- F. CARCINOMA INVOLVES BILATERAL SEMINAL VESICLES.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. MULTI-FOCAL PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS SEEN.
- J. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE (AJCC 7th EDITION): pT3b N0 MX.
- L. TNM HISTOLOGIC GRADE = G3.
- M. BACKGROUND PROSTATIC PARENCHYMA WITH FOCAL GLANDULAR HYPERPLASIA, FOCAL STROMAL HYPERPLASIA AND MILD TO MODERATE CHRONIC INFLAMMATION.

PART 4: URINARY BLADDER, RIGHT POSTERIOR MARGIN, EXCISION -

- A. FIBROMUSCULAR AND ADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.
- B. NO PROSTATIC TISSUE IS SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 56.7
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
Ductal adenocarcinoma
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 3
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 80%
WEIGHT OF PROSTATE: 47.55gm
TUMOR SIZE: Maximum dimension: 3.5 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: > 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: Yes - Established (> 0.8mm)
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: Yes
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 23
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3b
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICD-O-3

Adenocarcinoma w/mixed
subtypes 8255/3

Site Prostate NOS
061.9

JA 5/16/13

PATIENT HISTORY:

The patient is a -year-old black male with a history of PSA value of 56.4. The patient also has a history of biopsy on [REDACTED], this biopsy reveals: invasive prostatic adenocarcinoma, Gleason score $3+4 = 7$ and Gleason score $3+3 = 6$ in multiple cores.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

Histology Discrepancy		☒
Prin Malignancy History		☒

Source: NCI Genomic Data Commons file b6e3eb13-704d-4ab2-8376-69fb77ebf603 (TCGA-EJ-A65E.4B502278-393D-4B65-A424-B795547938ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).